Somatic mutation profile of tumor specimen TCGA-23-2649-01A (aliquot TCGA-23-2649-01A-01D-1526-09) from TCGA case TCGA-23-2649, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.8 years (22,210 days).
Specimen TCGA-23-2649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1090df35-6716-4de9-9e93-9bfbb9a2a83f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2649-10A (Blood Derived Normal), aliquot TCGA-23-2649-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ec01bab-5c2d-449e-ba23-a0805c4ab7c5

The open-access MAF lists 142 somatic variants for this specimen: 111 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 27, Nonsense Mutation 9, Frame Shift Del 8, Splice Site 3, Intron 2, In Frame Del 2, Nonstop Mutation 1, Frame Shift Ins 1, 3'Flank 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.702C>G p.Y234* | Nonsense Mutation (SNP) | VAF 197/252 reads (78%) | hotspot (GDC flag); catalogued as COSV52783916, COSV52908090, COSV53020803, COSV53124617; called by muse, mutect2, varscan2
- ABCB4 | c.3652A>G p.K1218E (on ENST00000265723 / NM_018849.3; = p.K1211E on NM_000443.4) | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55935365; called by muse, mutect2, varscan2
- ABCC6 | c.4263G>T p.Q1421H | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV52743812; called by muse, mutect2, varscan2
- ADAMTS12 | c.4631T>G p.L1544R | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61263016; called by muse, mutect2, varscan2
- ADAMTS7 | c.3454C>A p.P1152T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs761958725, COSV66307218; called by mutect2, varscan2
- ADGRG7 | c.1485C>A p.N495K | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.077); catalogued as COSV56296581; called by muse, mutect2, varscan2
- AIM2 | c.1027A>C p.T343P | Missense Mutation (SNP) | VAF 130/622 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs770198015, COSV63699722; called by mutect2, varscan2
- ALAS2 | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 75/446 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM1312006, COSV58190490; called by muse, mutect2, varscan2
- ALPK2 | c.2801C>G p.P934R | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV64492983, COSV64495079; called by muse, mutect2, varscan2
- APOB | c.12667G>C p.E4223Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as COSV51931369, COSV51935157; called by muse, mutect2, varscan2
- ATAD5 | c.2770A>T p.K924* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV58974587; called by muse, mutect2, varscan2
- CABS1 | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as COSV56733580; called by muse, mutect2, varscan2
- CLCNKA | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 92/356 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as COSV58891600; called by muse, mutect2, varscan2
- CNNM2 | c.36G>C p.K12N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV63995912; called by mutect2, varscan2
- CNTN1 | c.696A>G p.I232M | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV61639615; called by muse, mutect2, varscan2
- COL14A1 | c.4352G>A p.C1451Y | Missense Mutation (SNP) | VAF 33/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99917520; called by muse, mutect2
- CORO7-PAM16 | c.3102C>G p.I1034M | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1158360221, COSV52110610; called by muse, mutect2, varscan2
- CXorf66 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.316); catalogued as COSV100983798; called by muse, mutect2
- DGKD | c.2639G>C p.S880T (on ENST00000264057 / NM_152879.3; = p.S836T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/399 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as rs200902302, COSV51047333; called by muse, mutect2, varscan2
- DHDDS | c.884G>C p.R295P (on ENST00000236342 / NM_001319959.1; = p.R296P on NM_024887.3) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.286); catalogued as COSV52575942, COSV52576638; called by muse, mutect2, varscan2
- DNAH5 | c.8825C>G p.S2942C | Missense Mutation (SNP) | VAF 65/364 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54224521; called by muse, mutect2, varscan2
- DOP1A | c.2273C>G p.S758* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as COSV52718206, COSV99380569; called by muse, mutect2
- DOP1A | c.4913G>A p.G1638D | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472983932, COSV52710317; called by muse, mutect2, varscan2
- DRAM2 | c.693+2T>C p.X231_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as rs1369954809, COSV54415423; called by muse, mutect2, varscan2
- ELOA2 | c.1976A>G p.E659G | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55299053; called by muse, mutect2, varscan2
- EPS8L3 | c.976G>C p.A326P | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62609482; called by muse, mutect2, varscan2
- EXOG | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55063337; called by muse, mutect2, varscan2
- FAM47A | c.2053T>C p.S685P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV60496621; called by muse, mutect2, varscan2
- FCRL5 | c.2468A>G p.N823S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV62514510; called by muse, mutect2, varscan2
- FKBP1B | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV51980850; called by muse, mutect2, varscan2
- FLT1 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 85/346 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); catalogued as rs374468544, COSV99167645; called by muse, mutect2, varscan2
- FN1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 113/460 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201876289, COSV100115858, COSV60547906; called by muse, mutect2, varscan2
- GJB3 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64904592; called by muse, mutect2, varscan2
- GPAT3 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52357002; called by muse, mutect2, varscan2
- HNRNPA3 | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV66820819; called by muse, mutect2, varscan2
- HNRNPU | c.2045G>T p.G682V (on ENST00000283179; = p.G744V on NM_004501.3) | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51691119; called by muse, mutect2, varscan2
- IER3 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV52543874; called by muse, mutect2, varscan2
- IL10 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 71/366 reads (19%) | catalogued as COSV65594549; called by muse, mutect2, varscan2
- ILDR2 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54830909; called by muse, mutect2, varscan2
- IRAG1 | c.2129C>G p.P710R | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV70210886; called by muse, mutect2, varscan2
- IRAK1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs375736059, COSV57653822; called by muse, mutect2, varscan2
- KCNQ5 | c.672T>A p.N224K | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59659929; called by muse, mutect2, varscan2
- KIAA0100 | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV66492730; called by muse, mutect2, varscan2
- LILRB2 | c.1231A>G p.S411G | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100078829; called by muse, varscan2
- LIPI | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.785); catalogued as COSV60711529; called by muse, mutect2, varscan2
- LRP4 | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 146/559 reads (26%) | catalogued as COSV66135842; called by muse, varscan2
- MAP3K15 | c.2986G>T p.E996* | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | catalogued as COSV58830173; called by muse, mutect2, varscan2
- MCM2 | c.2099G>T p.S700I | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV54033724; called by muse, mutect2, varscan2
- MED16 | c.2257G>C p.G753R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV54126340; called by muse, mutect2, varscan2
- MFF | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 145/480 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV58825631; called by muse, mutect2, varscan2
- MMP15 | c.1007A>C p.Q336P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99539166; called by muse, varscan2
- MTA1 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV58757315; called by muse, varscan2
- MTRR | c.1409-2A>G p.X470_splice (on ENST00000264668; = p.X443_splice on NM_002454.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 25/157 reads (16%) | catalogued as COSV52943845; called by muse, mutect2, varscan2
- MYOCD | c.2567T>G p.I856S | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV58503590; called by muse, mutect2, varscan2
- NES | c.1520A>C p.K507T | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV63961034; called by muse, mutect2, varscan2
- NIPBL | c.7765C>T p.H2589Y | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1423499316, COSV56951230; called by muse, mutect2, varscan2
- NOL4 | c.1519A>G p.R507G | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1378746894, COSV52346811; called by muse, mutect2, varscan2
- NPNT | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59752614, COSV59753758; called by muse, mutect2, varscan2
- NUP107 | c.2533C>G p.Q845E | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV57494780; called by muse, mutect2, varscan2
- NUP85 | c.1413G>C p.K471N | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55456631; called by muse, mutect2, varscan2
- OIT3 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1422806408, COSV61826085; called by muse, mutect2, varscan2
- OR5AR1 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.354); catalogued as COSV57252648, COSV57252873, COSV57253800; called by muse, mutect2, varscan2
- OR8S1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100043417; called by muse, mutect2, varscan2
- OR8S1 | c.173C>G p.P58R | Missense Mutation (SNP) | VAF 69/335 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100043419; called by muse, mutect2, varscan2
- P2RX3 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54442610; called by muse, mutect2, varscan2
- PCYOX1L | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51002684; called by muse, mutect2, varscan2
- PDLIM7 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62883231; called by muse, mutect2, varscan2
- PELO | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50882059; called by muse, mutect2, varscan2
- PERP | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV69827517; called by muse, mutect2, varscan2
- PGBD5 | c.746A>T p.K249M (on ENST00000525115; = p.K318M on NM_001258311.2) | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58411748; called by muse, mutect2, varscan2
- PHLDB1 | c.302A>C p.N101T | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61878386; called by muse, mutect2, varscan2
- PICALM | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV62670737; called by muse, mutect2, varscan2
- PRICKLE1 | c.2326G>T p.G776* | Nonsense Mutation (SNP) | VAF 138/253 reads (55%) | catalogued as COSV58206914; called by muse, mutect2, varscan2
- RMND5B | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 35/71 reads (49%) | catalogued as rs749978415, COSV57744510; called by muse, mutect2, varscan2
- S100A9 | c.345A>C p.*115Yext*24 | Nonstop Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV64199670; called by muse, mutect2, varscan2
- SAPCD1 | c.421G>T p.G141W (on ENST00000425424; = p.G171W on NM_001039651.1) | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV100991666; called by muse, mutect2
- SCARA5 | c.946del p.D316Mfs*76 | Frame Shift Del (DEL) | VAF 89/260 reads (34%) | catalogued as rs1206242014, COSV57277325; called by mutect2*, pindel, varscan2*
- SH3PXD2A | c.3031G>C p.G1011R (on ENST00000369774 / NM_001365079.1; = p.G983R on NM_014631.2) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV60117152; called by muse, mutect2, varscan2
- SI | c.4208A>G p.N1403S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52278418; called by muse, mutect2, varscan2
- SLC11A1 | c.1628A>T p.D543V | Missense Mutation (SNP) | VAF 181/331 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV51917059; called by muse, mutect2, varscan2
- SLC22A7 | c.1247C>G p.A416G (on ENST00000372585 / NM_153320.2; = p.A414G on NM_006672.3) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV51483970, COSV51485833; called by muse, mutect2, varscan2
- SLC32A1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1414787318, COSV54146719, COSV99462079; called by muse, mutect2, varscan2
- SLC8A3 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63521169; called by muse, mutect2, varscan2
- SYTL2 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV60359086, COSV60363633; called by muse, mutect2, varscan2
- TAAR1 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as COSV51588466, COSV51588641; called by muse, mutect2
- TACR3 | c.709T>C p.W237R | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59201502; called by muse, mutect2, varscan2
- TCEAL1 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV65461101; called by muse, mutect2, varscan2
- TDGF1 | c.528G>T p.M176I | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV56126147; called by muse, mutect2, varscan2
- TECPR2 | c.2273A>G p.Y758C | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775251321, COSV63970559; called by muse, mutect2, varscan2
- TEX55 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.083); catalogued as COSV99817230; called by muse, mutect2
- TLCD5 | c.-1-4A>C | Splice Region (SNP) | VAF 54/182 reads (30%) | catalogued as COSV58755020; called by muse, mutect2, varscan2
- TMEM38A | c.825T>A p.H275Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV51819040; called by muse, mutect2, varscan2
- TP53BP2 | c.908A>G p.E303G (on ENST00000343537 / NM_001031685.3; = p.E174G on NM_005426.2) | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59068524; called by muse, mutect2, varscan2
- TRPV2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755817061, COSV58428263; called by muse, mutect2, varscan2
- TTC21B | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54630553; called by muse, mutect2, varscan2
- TTC3 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV61290177; called by muse, mutect2, varscan2
- VIM | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 61/436 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs371431143; called by muse, mutect2, varscan2
- VIT | c.1721C>T p.T574M (on ENST00000389975 / NM_001177969.1; = p.T589M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1044302467, COSV64896679; called by muse, mutect2, varscan2
- WDR37 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 74/486 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV54128837; called by muse, mutect2, varscan2
- CEP76 | c.1048C>G p.R350G | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.193); called by muse, varscan2
- DDX21 | c.1909del p.V637* | Frame Shift Del (DEL) | VAF 52/223 reads (23%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.5969del p.N1990Tfs*198 | Frame Shift Del (DEL) | VAF 31/59 reads (53%) | called by mutect2, pindel, varscan2
- LCT | c.4806_4807insT p.A1603Cfs*2 | Frame Shift Ins (INS) | VAF 50/216 reads (23%) | called by mutect2, pindel*, varscan2
- LRCH4 | c.992_1023del p.L331Qfs*14 | Frame Shift Del (DEL) | VAF 93/257 reads (36%) | called by mutect2, pindel, varscan2
- MMRN1 | c.3463_3475del p.S1155Lfs*4 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- MUC7 | c.120del p.K40Nfs*13 | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- NAA40 | c.69_89del p.V25_A31del | In Frame Del (DEL) | VAF 124/864 reads (14%) | called by mutect2, pindel
- RIPOR3 | c.56_76del p.V19_F25del | In Frame Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel
- SCARA5 | c.947del p.D316Vfs*76 | Frame Shift Del (DEL) | VAF 92/182 reads (51%) | called by mutect2, varscan2
- UTP20 | c.1996_2011del p.X666_splice | Splice Site (DEL) | VAF 35/157 reads (22%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.4653_4668del p.E1552Rfs*5 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.33C>T p.T11= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs1259454494, COSV57870442; called by muse, mutect2, varscan2
- BCAN | c.801G>A p.K267= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as COSV61256842; called by muse, mutect2, varscan2
- CCDC8 | c.627G>A p.R209= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1368528520, COSV56773306; called by muse, mutect2, varscan2
- CETN1 | c.366G>A p.S122= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs199682997, COSV59121265; called by muse, mutect2, varscan2
- COL22A1 | c.987T>C p.D329= | Silent (SNP) | VAF 44/495 reads (9%) | catalogued as COSV100275492; called by muse, mutect2
- CYP4F8 | c.120C>T p.A40= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57854015; called by muse, mutect2, varscan2
- GPC1 | c.858G>C p.L286= | Silent (SNP) | VAF 81/108 reads (75%) | catalogued as COSV50863382; called by muse, mutect2, varscan2
- GTF3C1 | c.453C>T p.I151= | Silent (SNP) | VAF 62/168 reads (37%) | catalogued as rs367815308; called by muse, mutect2, varscan2
- IFNAR1 | c.1197G>C p.L399= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV54252020; called by muse, mutect2, varscan2
- KLHL13 | c.1440C>T p.G480= | Silent (SNP) | VAF 77/329 reads (23%) | catalogued as COSV53247502; called by muse, mutect2, varscan2
- LAMB1 | c.276C>T p.D92= | Silent (SNP) | VAF 130/482 reads (27%) | catalogued as COSV55964546; called by muse, mutect2, varscan2
- LILRB2 | c.1230C>A p.P410= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV100078830, COSV58744441; called by muse, varscan2
- MARVELD2 | c.1456C>T p.L486= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as rs1307933711, COSV57780709; called by muse, mutect2, varscan2
- MEPCE | c.559C>T p.L187= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs1326453854, COSV52769206; called by muse, mutect2, varscan2
- PRRC2C | c.570T>C p.P190= (on ENST00000367742; = p.P188= on NM_015172.4) | Silent (SNP) | VAF 68/328 reads (21%) | catalogued as COSV58905275; called by muse, mutect2, varscan2
- PSD4 | c.2166C>G p.P722= | Silent (SNP) | VAF 68/209 reads (33%) | catalogued as COSV55526737; called by muse, mutect2, varscan2
- QSOX1 | c.1737C>T p.D579= | Silent (SNP) | VAF 50/253 reads (20%) | catalogued as rs755684560, COSV62580436; called by muse, mutect2, varscan2
- SEMA5B | c.2391G>A p.R797= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1354755978, COSV52097698; called by muse, mutect2, varscan2
- SIM1 | c.1989G>A p.S663= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as rs151274826; ClinVar: likely benign; called by muse, mutect2
- SLC12A4 | c.3084C>T p.V1028= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as COSV50452788; called by muse, mutect2, varscan2
- SLC6A3 | c.408C>T p.P136= | Silent (SNP) | VAF 59/359 reads (16%) | catalogued as COSV54364180; called by muse, mutect2, varscan2
- SPATA17 | c.729C>A p.P243= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV65121906, COSV65124603; called by muse, mutect2, varscan2
- TAOK1 | c.168C>T p.I56= | Silent (SNP) | VAF 72/227 reads (32%) | catalogued as COSV55591762, COSV55598310; called by muse, mutect2, varscan2
- TTLL5 | c.2004T>C p.N668= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV100088399, COSV54033650; called by muse, mutect2, varscan2
- UAP1 | c.18C>G p.L6= | Silent (SNP) | VAF 25/198 reads (13%) | catalogued as COSV54850649; called by muse, mutect2, varscan2
- WNK4 | c.1809G>A p.Q603= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs768020150, COSV55904734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF276 | c.576C>T p.S192= (on ENST00000443381 / NM_001113525.2; = p.S117= on NM_152287.4) | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs748624285, COSV57068193; called by muse, mutect2, varscan2
- BIN1 | c.858-1458G>T | Intron (SNP) | VAF 117/222 reads (53%) | catalogued as COSV52118413; called by muse, mutect2, varscan2
- SCML4 | c.157-5795G>C | Intron (SNP) | VAF 38/468 reads (8%) | catalogued as COSV100940115; called by muse, mutect2
- SLCO2A1 | chr3:133928772 T>A | 3'Flank (SNP) | VAF 8/41 reads (20%) | catalogued as COSV60485847; called by muse, mutect2, varscan2
- TUBB7P | n.864G>A | RNA (SNP) | VAF 9/33 reads (27%) | catalogued as rs782445968; called by muse, varscan2
